Somatic mutation profile of tumor specimen TCGA-QR-A6GW-01A (aliquot TCGA-QR-A6GW-01A-11D-A35D-08) from TCGA case TCGA-QR-A6GW, project TCGA-PCPG (Pheochromocytoma and Paraganglioma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Pheochromocytoma, NOS; Tissue or organ of origin: Adrenal gland, NOS; Age at diagnosis: 53.8 years (19,639 days).
Specimen TCGA-QR-A6GW-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 32230e93-179e-414b-9c6e-b057f33a19d1.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-QR-A6GW-10A (Blood Derived Normal), aliquot TCGA-QR-A6GW-10A-01D-A35B-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f11ded18-af20-4962-a37b-884a84b840a3

The open-access MAF lists 17 somatic variants for this specimen: 15 protein-altering or splice-affecting, 2 silent.
By variant classification: Missense Mutation 12, Silent 2, Nonsense Mutation 1, In Frame Del 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- HRAS | c.182A>G p.Q61R | Missense Mutation (SNP) | VAF 56/123 reads (46%) | hotspot (GDC flag); SIFT tolerated (0.07); PolyPhen benign (0.1); catalogued as rs121913233, COSV54236656, COSV54236691, COSV54238654; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- BCL2L2 | c.544del p.A182Pfs*3 | Frame Shift Del (DEL) | VAF 15/83 reads (18%) | catalogued as rs1441105135; called by mutect2, pindel, varscan2
- FRMPD4 | c.868G>A p.V290I | Missense Mutation (SNP) | VAF 34/125 reads (27%) | SIFT tolerated (0.1); PolyPhen benign (0.06); catalogued as rs779596855, COSV66218014; called by muse, mutect2, varscan2
- MUC16 | c.10585G>A p.D3529N | Missense Mutation (SNP) | VAF 53/245 reads (22%) | SIFT tolerated, low confidence (0.43); PolyPhen benign (0); catalogued as rs1483430115, COSV67453336, COSV67469378, COSV67496606; called by muse, mutect2, varscan2
- RNF20 | c.716_718del p.L239del | In Frame Del (DEL) | VAF 48/136 reads (35%) | catalogued as rs770441841; called by pindel, varscan2
- ZNF275 | c.984G>T p.K328N | Missense Mutation (SNP) | VAF 8/51 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1482142349; called by muse, mutect2, varscan2
- CDC42BPA | c.1000A>G p.I334V | Missense Mutation (SNP) | VAF 67/167 reads (40%) | SIFT tolerated (0.12); PolyPhen benign (0.106); called by muse, mutect2, varscan2
- GOLGA4 | c.3130A>T p.I1044L | Missense Mutation (SNP) | VAF 21/37 reads (57%) | SIFT tolerated (0.32); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- PHKA2 | c.3193G>A p.G1065S | Missense Mutation (SNP) | VAF 6/145 reads (4%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.991); called by muse, mutect2
- RANBP2 | c.7212G>A p.W2404* | Nonsense Mutation (SNP) | VAF 56/1052 reads (5%) | called by muse, mutect2
- TEC | c.1081G>A p.E361K | Missense Mutation (SNP) | VAF 10/178 reads (6%) | SIFT deleterious (0.03); PolyPhen benign (0.16); called by muse, mutect2
- TMEM208 | c.245A>G p.D82G | Missense Mutation (SNP) | VAF 18/33 reads (55%) | SIFT tolerated (0.19); PolyPhen benign (0.05); called by muse, mutect2, varscan2
- ZBTB14 | c.427A>C p.K143Q | Missense Mutation (SNP) | VAF 53/198 reads (27%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.788); called by muse, mutect2, varscan2
- ZNF516 | c.2432C>T p.S811F | Missense Mutation (SNP) | VAF 31/60 reads (52%) | SIFT deleterious (0); PolyPhen benign (0.063); called by muse, mutect2, varscan2
- ZNF613 | c.1415T>G p.I472S (on ENST00000293471 / NM_001031721.4; = p.I436S on NM_024840.4) | Missense Mutation (SNP) | VAF 40/93 reads (43%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- CACNA1F | c.3360C>T p.Y1120= | Silent (SNP) | VAF 17/42 reads (40%) | catalogued as rs1557107169; called by muse, mutect2, varscan2
- LATS2 | c.2658C>A p.L886= | Silent (SNP) | VAF 17/50 reads (34%) | called by muse, mutect2, varscan2
